Somatic mutation profile of tumor specimen TARGET-40-0A4I5B-01A (aliquot TARGET-40-0A4I5B-01A-01D) from TARGET case TARGET-40-0A4I5B, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 20.8 years (7,615 days).
Specimen TARGET-40-0A4I5B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48ed5c07-cee0-4599-8de8-353791feb96c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I5B-10A (Blood Derived Normal), aliquot TARGET-40-0A4I5B-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/852a1ccb-62e8-4309-831d-3a051fa54398

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.16333A>G p.K5445E | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1182573067; called by muse, mutect2, varscan2
- CUL1 | c.1607G>A p.S536N | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV57387950; called by muse, mutect2
- SCX | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs942996144; called by mutect2, varscan2
- KIF22 | c.148C>T p.L50= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1238919956; called by muse, mutect2, varscan2
- MAGEA6 | c.756G>A p.Q252= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1851C>T p.S617= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as COSV65364165; called by muse, mutect2, varscan2
